Surgical pathology report (de-identified scan), TCGA case TCGA-62-8397, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-8397-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, right, lower lobe: 16.0 x 8.5 x 7.0 cm

Tumor: 3.7 x 2.8 x 3.0 cm

Diagnosis:

Adenocarcinoma, mixed subtype (partially: papillary, acinar, mucinous)

Infiltration of pleura parietalis

pT3, pN0 (0/42), pMx, G2

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 1f9e417a-4126-4eee-b925-5901beb3c765 (TCGA-62-8397.129E57AB-653D-4B31-8777-0FDD6D01A89D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).